Somatic mutation profile of tumor specimen MP2PRT-PAUSLF-TMP1-A (aliquot MP2PRT-PAUSLF-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAUSLF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,249 days).
Specimen MP2PRT-PAUSLF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4acf2bef-d510-4964-93b8-8d43d9d38cbb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUSLF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUSLF-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3943ac2-71d4-40d1-b454-59024d2ee469

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 11, Silent 4, Splice Region 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.2049A>T p.R683S | Missense Mutation (SNP) | VAF 62/167 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519723, COSV67569539, COSV67577012; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.4213C>T p.R1405W | Missense Mutation (SNP) | VAF 176/446 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1057518049, COSV60795334; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ACACB | c.665C>T p.S222L | Missense Mutation (SNP) | VAF 89/304 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.573); catalogued as rs748928594; called by muse, mutect2, varscan2
- RPH3AL | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 102/289 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as rs375573295; called by muse, varscan2
- TRRAP | c.9406G>A p.E3136K (on ENST00000359863 / NM_001244580.1; = p.E3107K on NM_003496.3) | Missense Mutation (SNP) | VAF 90/226 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100722648, COSV62849388; called by muse, mutect2, varscan2
- ZBTB45 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 19/463 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1175973185, COSV63523351; called by muse, mutect2
- ABCA12 | c.5458A>C p.T1820P (on ENST00000272895 / NM_173076.3; = p.T1502P on NM_015657.3) | Missense Mutation (SNP) | VAF 81/209 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- AGFG2 | c.753C>G p.G251= | Splice Region (SNP) | VAF 66/197 reads (34%) | called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC61 | c.1056A>C p.K352N | Missense Mutation (SNP) | VAF 147/423 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- EPB41L3 | c.2998C>T p.P1000S | Missense Mutation (SNP) | VAF 14/326 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- IGHV1-69 | c.350_351insTCCGCGGC p.R117Sfs*? | Frame Shift Ins (INS) | VAF 16/82 reads (20%) | called by pindel, varscan2
- IGLV4-60 | chr22:22162675 del ACACTCACACAGTGATACAGGC | Missense Mutation (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel
- MVB12B | c.540-1G>A p.X180_splice | Splice Site (SNP) | VAF 70/219 reads (32%) | called by muse, mutect2, varscan2
- C6orf58 | c.496A>C p.R166= | Silent (SNP) | VAF 15/376 reads (4%) | called by muse, mutect2
- EPB42 | c.1101G>A p.P367= (on ENST00000441366 / NM_001114134.2; = p.P397= on NM_000119.3) | Silent (SNP) | VAF 16/281 reads (6%) | catalogued as rs1449860988, COSV55751408; called by muse, mutect2
- JPH4 | c.1572G>A p.G524= | Silent (SNP) | VAF 20/578 reads (3%) | catalogued as COSV58115241; called by muse, mutect2
- PKHD1 | c.6972C>A p.I2324= | Silent (SNP) | VAF 67/173 reads (39%) | catalogued as rs774455491, COSV61881760; called by muse, mutect2, varscan2
